Somatic mutation profile of tumor specimen TCGA-HD-8635-01A (aliquot TCGA-HD-8635-01A-11D-2394-08) from TCGA case TCGA-HD-8635, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.2 years (22,340 days).
Specimen TCGA-HD-8635-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61d6777c-4f96-4864-a7e9-b184dc6ea1be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-8635-10A (Blood Derived Normal), aliquot TCGA-HD-8635-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/957e90da-91aa-4721-b67b-eb44b9652f49

The open-access MAF lists 239 somatic variants for this specimen: 166 protein-altering or splice-affecting, 63 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 63, Nonsense Mutation 10, Intron 6, Splice Site 3, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 2, RNA 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.279+1G>A p.X93_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as rs886039246, CS134021, COSV99835037; ClinVar: pathogenic; called by muse, mutect2
- KMT2D | c.16295G>A p.R5432Q | Missense Mutation (SNP) | VAF 57/215 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123734, CM126446, COSV56409187, COSV99985294; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.3424A>T p.I1142F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99565552; called by muse, mutect2, varscan2
- ADCY8 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.971); catalogued as rs766510118, COSV53899701, COSV53911933; called by muse, mutect2, varscan2
- AFF2 | c.3179G>T p.R1060I | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99663174; called by muse, varscan2
- AGER | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 64/274 reads (23%) | catalogued as COSV100426151; called by muse, mutect2, varscan2
- AHR | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99619532; called by muse, mutect2, varscan2
- ALKBH8 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99508427, COSV99508661; called by muse, mutect2, varscan2
- AMER1 | c.2619G>C p.L873F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100365829; called by muse, mutect2
- ANAPC4 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100193943; called by muse, mutect2, varscan2
- ANK2 | c.5056G>A p.E1686K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100000889; called by mutect2, varscan2
- APOB | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs746414462, COSV51927055; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID1A | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1202361373, COSV61384914; called by muse, mutect2
- ARSF | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV100839474; called by muse, mutect2, varscan2
- ATP10B | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs374878756; called by muse, mutect2, varscan2
- ATP8B4 | c.951G>C p.K317N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV99464740; called by muse, mutect2, varscan2
- BAHCC1 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100311462; called by muse, mutect2, varscan2
- BCL9 | c.2191C>G p.Q731E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99324871; called by muse, mutect2, varscan2
- BMP5 | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100895878; called by muse, mutect2, varscan2
- BTC | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV101201508; called by muse, mutect2, varscan2
- CEP192 | c.3260T>A p.M1087K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100381005; called by muse, mutect2, varscan2
- CES2 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1481632119, COSV100399024, COSV100399176; called by muse, mutect2, varscan2
- CFAP94 | c.1962G>C p.K654N (on ENST00000320267 / NM_001352064.2; = p.K660N on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100209177; called by mutect2, varscan2
- CHRDL1 | c.1229G>A p.W410* (on ENST00000372045; = p.W416* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV54329312; called by muse, mutect2, varscan2
- CLBA1 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV101121007, COSV66347775; called by muse, mutect2, varscan2
- CLCA4 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV99760403; called by muse, varscan2
- CNTLN | c.1962T>A p.N654K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV99263617; called by muse, mutect2, varscan2
- CPM | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100615016; called by muse, mutect2, varscan2
- CXorf66 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.414); catalogued as COSV100983864; called by muse, mutect2, varscan2
- CYLC1 | c.1417A>C p.K473Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV100254433; called by muse, mutect2
- CYTH1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100739257; called by muse, mutect2, varscan2
- DDX51 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100223024; called by muse, mutect2, varscan2
- DEPDC7 | c.559C>T p.H187Y (on ENST00000241051 / NM_001077242.2; = p.H178Y on NM_139160.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99572650; called by muse, mutect2
- DHRS9 | c.209A>T p.K70M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100513416; called by muse, mutect2, varscan2
- DNAJC4 | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99655765; called by muse, mutect2
- DOCK11 | c.5782G>C p.E1928Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352689; called by muse, mutect2, varscan2
- EDC4 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV100197589; called by muse, mutect2, varscan2
- EEF1A1 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as COSV100303263; called by muse, mutect2, varscan2
- ELOVL4 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100876225; called by muse, mutect2
- EML2 | c.479G>C p.R160T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99839855; called by muse, mutect2, varscan2
- EML3 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.463); catalogued as COSV99609732; called by muse, mutect2, varscan2
- EML4 | c.2599A>C p.K867Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100580811; called by muse, mutect2, varscan2
- ERICH3 | c.1745C>A p.S582* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100443950; called by muse, mutect2, varscan2
- EXOC1 | c.1954-2A>C p.X652_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100637823; called by muse, mutect2
- FAM114A2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as COSV100697632; called by muse, mutect2, varscan2
- FASTKD3 | c.1804T>C p.C602R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99242487; called by muse, mutect2, varscan2
- FBXO10 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs753699828, COSV52835886; called by muse, mutect2, varscan2
- FBXO42 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs760530903, COSV65046371; called by muse, mutect2, varscan2
- GCOM1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV99984812; called by muse, mutect2, varscan2
- GOLGB1 | c.7059G>C p.K2353N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs754411553, COSV100510638; called by muse, mutect2, varscan2
- GPATCH3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100658753, COSV64652596; called by muse, mutect2, varscan2
- GPR61 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.346); catalogued as COSV100879859; called by muse, mutect2, varscan2
- GRK2 | c.1453A>T p.I485F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100419630; called by muse, mutect2, varscan2
- H2AC8 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99773168; called by muse, mutect2, varscan2
- HMGN3 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99245595; called by muse, mutect2, varscan2
- HPDL | c.933del p.I312Sfs*3 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as COSV100588014; called by mutect2, pindel, varscan2
- HYAL4 | c.45A>T p.Q15H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV99772179; called by muse, mutect2, varscan2
- IGF2R | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV100807192, COSV63632369; called by muse, mutect2, varscan2
- IGF2R | c.7291A>T p.S2431C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100807194; called by muse, mutect2, varscan2
- ITGAD | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs763618394, COSV101210424; called by muse, mutect2, varscan2
- ITGAL | c.2973G>T p.Q991H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100776189; called by muse, mutect2, varscan2
- ITSN1 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV101180471; called by muse, mutect2, varscan2
- JADE1 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV99885618; called by muse, mutect2, varscan2
- JAK3 | c.2899G>C p.D967H | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101512910; called by muse, varscan2
- KCNB2 | c.2516G>A p.S839N | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV101578733; called by muse, mutect2, varscan2
- KCND2 | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100474975; called by muse, mutect2, varscan2
- KCNJ14 | c.1103A>T p.E368V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100655757; called by muse, mutect2, varscan2
- KLHL30 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100014210; called by muse, mutect2, varscan2
- LAMB4 | c.3837G>C p.K1279N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV99223574; called by muse, mutect2, varscan2
- LAP3 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as COSV99884214; called by muse, mutect2
- LIN54 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV61202800, COSV61203289; called by muse, mutect2, varscan2
- LRRTM1 | c.691C>A p.R231S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54447186, COSV99702237; called by muse, mutect2, varscan2
- MACF1 | c.6421C>T p.P2141S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99243282; called by muse, mutect2, varscan2
- MAP3K4 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs757881893, COSV100815234; called by muse, mutect2, varscan2
- MASP1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs766084598, COSV51461074; called by muse, mutect2, varscan2
- MCM8 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99177548; called by muse, varscan2
- MEGF10 | c.1375A>G p.K459E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as rs79671291, COSV99174835; called by muse, mutect2, varscan2
- MGAM | c.2080C>A p.Q694K | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101527443; called by muse, mutect2, varscan2
- MIGA1 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as COSV100889762; called by muse, mutect2, varscan2
- MOXD1 | c.980A>T p.Y327F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV60947004; called by muse, mutect2, varscan2
- MRPL42 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100696604, COSV62355587, COSV62357065; called by muse, mutect2, varscan2
- MUC16 | c.43436G>A p.R14479H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs61748893; called by muse, mutect2, varscan2
- NCAPG2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1260371915, COSV99316808; called by muse, mutect2, varscan2
- NCOA2 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101475933; called by muse, mutect2, varscan2
- NOS1AP | c.414C>A p.S138R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100723079, COSV100723685; called by muse, mutect2, varscan2
- NOTCH1 | c.4202G>A p.G1401E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53083534; called by muse, mutect2, varscan2
- OPRM1 | c.35A>G p.N12S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs199645285, COSV100000974; called by muse, mutect2
- OR2G2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV60740194, COSV60740632; called by muse, varscan2
- OR4Q3 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV100056930; called by muse, mutect2, varscan2
- OR52R1 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100617691, COSV61888291; called by muse, mutect2, varscan2
- OR52R1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.118); catalogued as COSV100617693; called by muse, mutect2, varscan2
- ORC1 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856643; called by muse, mutect2
- ORC6 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99530848; called by muse, mutect2, varscan2
- PALD1 | c.1841G>T p.R614L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99698177; called by muse, mutect2, varscan2
- PAPPA2 | c.1837C>G p.R613G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV100866517, COSV100866713, COSV100867066; called by muse, mutect2, varscan2
- PCDH15 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.028); catalogued as COSV100218814; called by muse, mutect2, varscan2
- PCDH18 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100787204; called by muse, mutect2, varscan2
- PCDH18 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100787205; called by muse, mutect2, varscan2
- PCDHA1 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV65373454; called by muse, mutect2, varscan2
- PCNX1 | c.1766C>G p.T589S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as rs767319145, COSV99455145; called by muse, mutect2, varscan2
- PFDN4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV101004615, COSV65063404; called by muse, mutect2, varscan2
- PIGG | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV99573763; called by muse, mutect2, varscan2
- PIK3CB | c.1237A>G p.T413A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1348630621, COSV100005452; called by muse, mutect2, varscan2
- PLPPR4 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100926757; called by muse, mutect2, varscan2
- PRKDC | c.4689C>G p.F1563L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100039759; called by muse, mutect2, varscan2
- PRKG2 | c.1574A>T p.Y525F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as rs143281279, COSV100019661; called by muse, mutect2, varscan2
- PRSS16 | c.1279T>A p.S427T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV100041660; called by muse, mutect2, varscan2
- PRTG | c.2840C>G p.S947* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101221344; called by muse, varscan2
- PTPN7 | c.467G>C p.R156P (on ENST00000495688; = p.R195P on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100459790; called by muse, mutect2, varscan2
- PTPRZ1 | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV101099916; called by muse, mutect2, varscan2
- PYGO1 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs778829834, COSV100114583; called by muse, mutect2, varscan2
- RAB33B | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99978176; called by muse, mutect2, varscan2
- RASGRP1 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100171870; called by muse, mutect2, varscan2
- RBBP5 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as COSV99196783; called by muse, mutect2, varscan2
- RBM33 | c.2951A>T p.K984M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265335; called by muse, mutect2
- RCC1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs751946002, COSV100868095; called by muse, mutect2, varscan2
- RDH12 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961816; called by muse, mutect2, varscan2
- RIPK3 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99353118; called by muse, mutect2, varscan2
- RNF123 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100570560; called by muse, mutect2, varscan2
- RPS6KA1 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV100837920; called by muse, mutect2, varscan2
- RSPRY1 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV101070973, COSV68027577; called by muse, mutect2, varscan2
- SCRT1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100146405; called by muse, mutect2
- SEMA4C | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.593); catalogued as COSV100560855; called by muse, varscan2
- SIM1 | c.2287A>G p.T763A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.06); catalogued as COSV99492224; called by muse, mutect2, varscan2
- SLC26A4 | c.2231A>G p.E744G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99706795; called by muse, mutect2
- SLC44A5 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100901735; called by muse, mutect2, varscan2
- SMAD4 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61686851; called by muse, mutect2, varscan2
- SMTN | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs758896914, COSV100294225; called by muse, mutect2, varscan2
- SNX10 | c.210G>C p.L70= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100640061; called by mutect2, varscan2
- SOGA3 | c.1674G>C p.Q558H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100846866; called by muse, mutect2, varscan2
- SPAM1 | c.907T>A p.Y303N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755292470, COSV56141179; called by muse, mutect2, varscan2
- SPEN | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 18/282 reads (6%) | catalogued as COSV101005122; called by muse, mutect2
- SPO11 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV100625672; called by muse, mutect2, varscan2
- STK17B | c.657G>C p.W219C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99826054; called by muse, mutect2
- SYNE2 | c.18220G>A p.E6074K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100647347; called by muse, mutect2, varscan2
- SYT6 | c.464G>A p.R155H (on ENST00000610222 / NM_001366225.1; = p.R70H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs138691067; called by muse, mutect2, varscan2
- TCTE3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV100825399, COSV100825409; called by muse, mutect2, varscan2
- THBS1 | c.3071G>C p.G1024A | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52949960, COSV99527810; called by muse, mutect2, varscan2
- TM7SF3 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV100544751; called by muse, mutect2, varscan2
- TOP1MT | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100239332; called by muse, mutect2, varscan2
- TOPORS | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs769612556, COSV100859488; called by muse, mutect2, varscan2
- TPCN2 | c.429+1G>A p.X143_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as rs1256899842, COSV99593408; called by muse, mutect2, varscan2
- TRPS1 | c.60C>G p.I20M (on ENST00000220888 / NM_001330599.2; = p.I33M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs61758125, COSV99629812; called by muse, mutect2, varscan2
- TTC29 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as COSV100283554; called by muse, mutect2
- TTF2 | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101037389; called by muse, mutect2
- TUBB1 | c.949T>C p.F317L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as COSV99414007; called by muse, mutect2
- UBAC2 | c.816G>C p.M272I (on ENST00000403766 / NM_001144072.2; = p.M237I on NM_177967.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63121249; called by muse, mutect2, varscan2
- UGGT2 | c.4194G>C p.K1398N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100948512; called by muse, mutect2
- ULK1 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs937151694, COSV100416729; called by muse, mutect2, varscan2
- UMPS | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99228926; called by muse, mutect2, varscan2
- USP34 | c.4945G>T p.D1649Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101276899, COSV68404783; called by mutect2, varscan2
- VPS13C | c.5768G>T p.W1923L (on ENST00000644861 / NM_020821.3; = p.W1880L on NM_017684.5) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99828038; called by muse, mutect2, varscan2
- VPS13D | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV62535261; called by muse, mutect2
- WARS2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.148); catalogued as rs753141532, COSV52477902; called by muse, mutect2, varscan2
- XPOT | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100225449; called by muse, mutect2, varscan2
- ZFP37 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100953233; called by muse, mutect2, varscan2
- ZNF396 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs369731655; called by muse, mutect2, varscan2
- ZNF878 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV101521174, COSV72156121; called by muse, mutect2, varscan2
- DNM2 | c.1738_1742del p.M580Qfs*27 (on ENST00000355667 / NM_001005360.3; = p.M576Qfs*27 on NM_004945.3) | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- GDF10 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- LAMB1 | c.1709dup p.V571Sfs*23 | Frame Shift Ins (INS) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- NNT | c.864dup p.A289Cfs*10 | Frame Shift Ins (INS) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- SPIN3 | c.518dup p.Y173* | Nonsense Mutation (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- TBX6 | c.1277_1288del p.G426_D429del | In Frame Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ABCA12 | c.3837C>T p.Y1279= (on ENST00000272895 / NM_173076.3; = p.Y961= on NM_015657.3) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs763069319, COSV99789391; called by muse, mutect2, varscan2
- ABCC3 | c.3342C>A p.V1114= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV99558981; called by muse, mutect2, varscan2
- ADGRA3 | c.3849C>G p.L1283= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99293155; called by muse, mutect2, varscan2
- ALG3 | c.546C>T p.L182= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99891049; called by muse, mutect2
- AP4M1 | c.135C>A p.S45= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1212435300, COSV100384827; called by muse, mutect2, varscan2
- ARHGAP26 | c.1800C>G p.P600= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs1312884552, COSV99190497; called by muse, mutect2, varscan2
- ASB16 | c.24C>T p.F8= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs761508752, COSV99518809; called by muse, mutect2, varscan2
- C16orf72 | c.258C>G p.L86= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100589020; called by muse, mutect2, varscan2
- CACNA1H | c.993C>T p.G331= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs770821118, COSV100670762, COSV62000679; called by muse, mutect2, varscan2
- CDHR2 | c.3705C>A p.L1235= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV56137878, COSV99991390; called by muse, mutect2, varscan2
- CENPK | c.528C>G p.L176= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54467377; called by muse, mutect2, varscan2
- CFAP65 | c.2052C>A p.I684= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1448576189, COSV100444950, COSV58562950; called by muse, mutect2, varscan2
- CHRNG | c.885G>T p.V295= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV101263924; called by muse, mutect2, varscan2
- COL11A1 | c.1380C>T p.G460= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100615947; called by muse, mutect2, varscan2
- COQ7 | c.372G>A p.A124= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs767617457, COSV58982935; called by muse, mutect2, varscan2
- DEF6 | c.438G>A p.L146= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100359249; called by muse, mutect2, varscan2
- EGFL8 | c.93C>T p.L31= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100246887; called by muse, mutect2, varscan2
- ELMO1 | c.2136G>A p.P712= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs892851067, COSV100164009; called by muse, mutect2, varscan2
- FAM160B1 | c.1110C>T p.L370= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100985390; called by muse, mutect2, varscan2
- FKBP5 | c.1176C>G p.S392= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV100616130; called by muse, mutect2, varscan2
- FRMD1 | c.249G>A p.V83= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV99349660; called by muse, mutect2, varscan2
- FSCB | c.174T>A p.T58= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100469158; called by muse, mutect2, varscan2
- FSIP2 | c.18132G>T p.L6044= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100554770; called by muse, varscan2
- GRIA3 | c.414C>A p.V138= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV99989662; called by muse, mutect2, varscan2
- GUCY2C | c.2028G>A p.R676= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV53789847; called by muse, mutect2, varscan2
- HTR3A | c.1225C>A p.R409= | Silent (SNP) | VAF 85/148 reads (57%) | catalogued as COSV55470741, COSV55471627; called by muse, mutect2, varscan2
- IKZF2 | c.264C>T p.S88= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs374835918; called by muse, mutect2, varscan2
- IPO8 | c.2442T>C p.T814= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99805083; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1023C>G p.L341= (on ENST00000439118 / NM_001008949.3; = p.L349= on NM_178495.6) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100742177, COSV63154477; called by muse, mutect2, varscan2
- JAKMIP2 | c.255G>T p.L85= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as rs530786010, COSV99507966; called by muse, mutect2, varscan2
- KLHL17 | c.1899G>A p.P633= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs753204975, COSV100647471; called by muse, mutect2, varscan2
- KPNA4 | c.489G>C p.L163= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100515121; called by muse, mutect2, varscan2
- LPCAT1 | c.1458C>T p.F486= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as rs772635191, COSV52041759; called by muse, mutect2, varscan2
- LRRC36 | c.1713G>A p.P571= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs371561086; called by muse, mutect2, varscan2
- MFSD13A | c.948T>C p.H316= | Silent (SNP) | VAF 35/193 reads (18%) | catalogued as COSV99487812; called by muse, mutect2, varscan2
- MTMR14 | c.642G>A p.L214= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99931218; called by muse, mutect2, varscan2
- NFYC | c.150G>A p.K50= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100438362; called by muse, mutect2, varscan2
- NIPAL1 | c.1023G>C p.L341= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs752078088, COSV55006328; called by muse, mutect2, varscan2
- PAGR1 | c.84C>G p.L28= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100232655, COSV100232811; called by muse, mutect2, varscan2
- PCDHA6 | c.1893C>A p.I631= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV100971384; called by muse, mutect2, varscan2
- PCDHGB3 | c.1533C>T p.S511= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs750914672, COSV53987983, COSV53996649; called by muse, mutect2, varscan2
- PPP3CA | c.1473C>T p.P491= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs772699276, COSV100547505; called by muse, mutect2, varscan2
- RHCE | c.792G>A p.K264= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV99603931; called by muse, mutect2, varscan2
- SART3 | c.2229C>T p.L743= (on ENST00000228284; = p.L725= on NM_014706.4) | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99934003; called by muse, mutect2, varscan2
- SBK1 | c.144C>T p.D48= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs767031209, COSV100543466; called by muse, mutect2, varscan2
- SEMA4C | c.1452C>T p.L484= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100560857; called by muse, mutect2
- SEMA4C | c.342C>T p.I114= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1409165576, COSV100560859; called by muse, mutect2, varscan2
- SGK2 | c.489C>T p.F163= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58315940; called by muse, mutect2, varscan2
- SHPRH | c.213G>A p.K71= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99261848; called by muse, mutect2, varscan2
- SLC4A4 | c.42C>G p.L14= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99139706; called by muse, mutect2, varscan2
- SLITRK4 | c.2382G>A p.L794= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV100567268; called by muse, mutect2, varscan2
- SMG5 | c.1173C>T p.L391= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs752939820, COSV62435099; called by muse, mutect2, varscan2
- SPINK14 | c.162C>G p.V54= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100810973; called by muse, mutect2, varscan2
- SRRT | c.1305C>T p.A435= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1307079534, COSV53815285; called by muse, mutect2, varscan2
- ST14 | c.651C>A p.G217= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99598634; called by muse, mutect2, varscan2
- TENM2 | c.4074G>A p.P1358= (on ENST00000518659 / NM_001122679.2; = p.P1119= on NM_001080428.3) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs374089694, COSV69132154; called by muse, mutect2, varscan2
- TMEM270 | c.21C>G p.V7= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100260328, COSV57638508; called by muse, mutect2, varscan2
- TRAPPC9 | c.2298C>T p.F766= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs770060414, COSV101227167, COSV66907982; called by muse, mutect2, varscan2
- TRPV3 | c.195C>G p.S65= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100027624; called by muse, mutect2, varscan2
- VPS51 | c.1545G>A p.K515= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs369231552, COSV99659530; called by muse, mutect2, varscan2
- ZBTB40 | c.3504C>T p.A1168= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs139786086; called by muse, mutect2, varscan2
- ZNF454 | c.471C>T p.S157= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- ZNF831 | c.789C>G p.T263= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100925950; called by muse, mutect2, varscan2
- MEF2D | c.-1G>T | 5'UTR (SNP) | VAF 32/127 reads (25%) | catalogued as COSV100559960; called by muse, mutect2
- MIF4GD | c.82+765G>C | Intron (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99821541; called by muse, mutect2, varscan2
- NACA | c.71-3552A>G | Intron (SNP) | VAF 23/87 reads (26%) | catalogued as rs780975438, COSV100771225; called by muse, mutect2, varscan2
- NOXRED1 | c.682+56A>T | Intron (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100033012; called by muse, mutect2, varscan2
- PHACTR4 | c.1816+634G>C | Intron (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100868425; called by muse, mutect2, varscan2
- PKP4 | c.-2G>C | 5'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101080675; called by muse, mutect2
- RPL26P30 | n.984G>C | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- RPL39 | c.108-696G>A | Intron (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100846464; called by muse, mutect2, varscan2
- SLC12A6 | c.271+17788G>T | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99271611; called by muse, mutect2, varscan2
- SNORD114-17 | n.36T>A | RNA (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
